Somatic mutation profile of tumor specimen TCGA-WR-A838-01A (aliquot TCGA-WR-A838-01A-12D-A403-09) from TCGA case TCGA-WR-A838, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.3 years (26,418 days).
Specimen TCGA-WR-A838-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 652632b7-7c35-4829-8a43-b4becc7f6504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WR-A838-10A (Blood Derived Normal), aliquot TCGA-WR-A838-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcf8ca3c-42a6-420d-a607-7957efb1668e

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 18, Silent 13, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.1399del p.E467Kfs*27 (on ENST00000295851 / NM_001375719.1; = p.E429Kfs*27 on NM_005759.7 and 35 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV53694210; called by mutect2, pindel, varscan2
- CDH23 | c.4562A>G p.N1521S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs780987516, CM1512995, COSV99821458; called by muse, mutect2, varscan2
- CIDEA | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140796846, COSV100255117; called by muse, mutect2
- CNOT3 | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV99651965; called by muse, mutect2, varscan2
- FBH1 | c.500A>G p.E167G (on ENST00000362091 / NM_178150.3; = p.E218G on NM_032807.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1347003753, COSV100758783; called by muse, mutect2, varscan2
- GRID1 | c.2481G>T p.K827N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV100024412; called by muse, mutect2, varscan2
- HNRNPM | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100335226; called by muse, mutect2, varscan2
- HYDIN | c.3229A>G p.I1077V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs6416709, COSV66829418; called by muse, mutect2
- IZUMO2 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99518286; called by muse, mutect2, varscan2
- LACC1 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100354684, COSV100354762; called by muse, mutect2, varscan2
- LNX1 | c.1222A>G p.I408V (on ENST00000263925 / NM_001126328.3; = p.I312V on NM_032622.2) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as COSV99820053; called by muse, mutect2, varscan2
- OR4C12 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100078539; called by muse, mutect2, varscan2
- PAGE3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100891988; called by muse, mutect2
- RADIL | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs547243389, COSV68200551; called by muse, mutect2, varscan2
- RPS16 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.157); catalogued as rs144170206; called by muse, mutect2, varscan2
- SGMS2 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62988865; called by muse, varscan2
- SLC6A17 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770108919, COSV100521354; called by muse, mutect2, varscan2
- SYNE2 | c.13765C>G p.L4589V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100647858; called by muse, mutect2, varscan2
- TP53 | c.380_381delinsA p.S127Yfs*43 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as COSV53251739; called by pindel, varscan2*
- TRPM1 | c.4321G>A p.V1441I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as rs771308316, COSV56643455; called by muse, mutect2, varscan2
- GABBR2 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- MAGI1 | c.2364dup p.P789Tfs*5 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- GABRA5 | c.990C>T p.F330= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs1417092187, COSV59487726; called by muse, mutect2, varscan2
- HCK | c.279C>T p.H93= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1301743269, COSV52948044, COSV99394111; called by muse, mutect2, varscan2
- ITGA8 | c.3012G>A p.P1004= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs147846713, COSV65224013; called by muse, mutect2, varscan2
- KCNA6 | c.516G>A p.P172= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs758711143, COSV99768696; called by muse, mutect2, varscan2
- MAP2 | c.4347A>G p.E1449= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV52289833; called by muse, mutect2, varscan2
- NEK10 | c.3333A>G p.G1111= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99835273; called by mutect2, varscan2
- NIBAN2 | c.1236G>A p.L412= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV64825354; called by muse, mutect2, varscan2
- OR51G2 | c.135G>A p.P45= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs554121981, COSV100432152; called by muse, mutect2, varscan2
- OR5B12 | c.231C>A p.P77= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100222458; called by muse, mutect2, varscan2
- PCDHGA3 | c.2139G>C p.A713= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV99539845; called by muse, varscan2
- SIN3B | c.2055C>T p.G685= | Silent (SNP) | VAF 50/246 reads (20%) | catalogued as COSV99931785; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.663A>T p.T221= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99143325; called by muse, mutect2, varscan2
- UBQLN3 | c.315C>A p.A105= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100293734; called by muse, mutect2, varscan2
